Somatic mutation profile of tumor specimen 0DKDDK from CCDI case PBBXYM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.1 years (1,501 days).
Specimen 0DKDDK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0347d088-3a7f-4bff-ad78-461c1d96e43a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKDBX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/015f679b-c53a-4f24-947c-a621ccc8a5be

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 3, Nonsense Mutation 2, 5'UTR 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 463/1171 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52517710, COSV52518111; called by muse, mutect2, varscan2
- PTPN11 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 217/557 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121918468, CM043335, CM096577, COSV100692090, COSV61005148; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 272/448 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TIMELESS | c.3362C>T p.S1121F | Missense Mutation (SNP) | VAF 320/1144 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV57511727; called by muse, mutect2, varscan2
- TMEM132B | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 114/1871 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs775349963, COSV100170770; called by muse, mutect2
- UGT3A2 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 394/1018 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs774867868, COSV56928601; called by muse, mutect2, varscan2
- ZNF98 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 65/553 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV63336012; called by muse, mutect2, varscan2
- CLRN1 | c.476T>A p.V159E (on ENST00000327047 / NM_174878.3; = p.V83E on NM_052995.2) | Missense Mutation (SNP) | VAF 74/2643 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- CT47B1 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 279/660 reads (42%) | called by muse, mutect2, varscan2
- FAM120B | c.2644G>A p.G882R | Missense Mutation (SNP) | VAF 80/916 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.79); called by muse, mutect2
- GGT7 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 80/860 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- GM2A | c.297C>A p.C99* | Nonsense Mutation (SNP) | VAF 92/1268 reads (7%) | called by muse, mutect2
- MYH8 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 139/1067 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PPP3CB | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM1 | c.1646G>T p.C549F | Missense Mutation (SNP) | VAF 68/1464 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- USP46 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 126/2528 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.327); called by muse, mutect2
- USP46 | c.373T>A p.L125I | Missense Mutation (SNP) | VAF 83/1983 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- USP6 | c.2065G>A p.V689I | Missense Mutation (SNP) | VAF 68/1392 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- YME1L1 | c.2164A>C p.R722= (on ENST00000326799 / NM_139312.3; = p.R665= on NM_014263.4) | Silent (SNP) | VAF 442/1222 reads (36%) | called by muse, mutect2, varscan2
- CRYAB | c.202-79G>A | Intron (SNP) | VAF 43/117 reads (37%) | called by muse, mutect2, varscan2
- CXorf65 | c.112+29C>T | Intron (SNP) | VAF 263/667 reads (39%) | called by muse, mutect2, varscan2
- FAM20A | c.*47G>C | 3'UTR (SNP) | VAF 112/287 reads (39%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92727T>A | Intron (SNP) | VAF 752/1095 reads (69%) | called by muse, mutect2, varscan2
- RRP36 | c.-18G>T | 5'UTR (SNP) | VAF 176/543 reads (32%) | catalogued as rs1382943519; called by muse, mutect2, varscan2
